FM case AD9203 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/233678b3-157d-4537-a634-e25eab30c42f

Female, 62.4 years: Thymoma, NOS (ICD-O-3 8580/1) of the thymus; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
